Somatic mutation profile of tumor specimen C3L-02549-02 (aliquot CPT0113210009) from CPTAC case C3L-02549, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 69.7 years (25,447 days).
Specimen C3L-02549-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57d10e63-be03-4890-92a0-9ee6c9f6cab4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02549-31 (Blood Derived Normal), aliquot CPT0115250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc1663c-58a0-4884-bd0f-5940b351504a

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Frame Shift Del 3, Intron 2, Silent 1, 5'UTR 1, 3'UTR 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/367 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786201090, CD044169, CM981870, COSV58820334, COSV58822715; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1844G>A p.R615K (on ENST00000288602 / NM_001374244.1; = p.R575K on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV56137419; called by muse, mutect2
- IL13RA1 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs1264214387; called by muse, mutect2, varscan2
- KIAA0232 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV56926579; called by muse, mutect2, varscan2
- LRRC7 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs376248362; called by muse, mutect2, varscan2
- NBEAL1 | c.4100A>G p.N1367S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71375038; called by muse, mutect2, varscan2
- PRPS1L1 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 85/572 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV72649896; called by muse, mutect2, varscan2
- SIGLEC5 | c.563del p.L188Rfs*28 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | catalogued as rs757523146, COSV99707258; called by mutect2, varscan2
- SMARCA4 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs1046318786, COSV60790543, COSV60799188; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS8 | c.2456G>A p.S819N | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CAPN13 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CPSF1 | c.746A>C p.Q249P | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2
- GUCY2D | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSPA8 | c.492T>G p.I164M | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ITGA11 | c.2402C>A p.T801K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- MGA | c.2189-2_2191delinsTTTTT p.X730_splice | Splice Site (ONP) | VAF 8/99 reads (8%) | called by mutect2*, pindel
- MTRES1 | c.109_115del p.T37Gfs*27 | Frame Shift Del (DEL) | VAF 34/305 reads (11%) | called by mutect2, pindel
- OR8K5 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PROCR | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); called by mutect2, varscan2
- SETD1B | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A5 | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SLC6A14 | c.222del p.L75* | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.2649_2660del p.H884_K887del | In Frame Del (DEL) | VAF 42/229 reads (18%) | called by mutect2, pindel, varscan2
- UBIAD1 | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF470 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.8886C>T p.R2962= (on ENST00000360013 / NM_001024660.4; = p.R1265= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/221 reads (16%) | called by muse, mutect2, varscan2
- IL10RA | c.*1548T>G | 3'UTR (SNP) | VAF 35/562 reads (6%) | called by muse, mutect2
- PDE6B | c.1059+49G>A | Intron (SNP) | VAF 45/323 reads (14%) | catalogued as rs754944496; called by muse, mutect2, varscan2
- TMEM192 | c.-28C>T | 5'UTR (SNP) | VAF 25/122 reads (20%) | catalogued as rs780527147; called by muse, mutect2, varscan2
- TNNI3 | c.109-13C>A | Intron (SNP) | VAF 58/325 reads (18%) | called by muse, mutect2, varscan2
